Somatic mutation profile of tumor specimen TCGA-HT-A5RC-01A (aliquot TCGA-HT-A5RC-01A-11D-A289-08) from TCGA case TCGA-HT-A5RC, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 70.6 years (25,772 days).
Specimen TCGA-HT-A5RC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 34a85d6d-7a06-489a-bfaf-290214ca4255.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-A5RC-10A (Blood Derived Normal), aliquot TCGA-HT-A5RC-10A-01D-A289-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6653b3d0-014e-44b8-861e-2ec81bcf5856

The open-access MAF lists 58 somatic variants for this specimen: 42 protein-altering or splice-affecting, 11 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 11, Intron 4, Nonsense Mutation 1, 3'Flank 1, In Frame Del 1, Splice Site 1, Frame Shift Del 1, Splice Region 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.1793G>T p.G598V | Missense Mutation (SNP) | VAF 1392/3269 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs139236063, COSV51769031, COSV51808387; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABLIM3 | c.1345C>T p.R449W | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs139404389; called by muse, mutect2
- ACSBG1 | c.2024G>A p.R675Q | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as rs548841663, COSV51911549, COSV99357610; called by muse, mutect2, varscan2
- ADGRG2 | c.997C>T p.H333Y (on ENST00000379869 / NM_001079858.3; = p.H330Y on NM_005756.4) | Missense Mutation (SNP) | VAF 98/287 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.102); catalogued as COSV61341694; called by muse, mutect2, varscan2
- CALML3 | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1327202118, COSV59450316; called by muse, mutect2, varscan2
- CCDC30 | c.1985G>A p.R662Q (on ENST00000340612; = p.R619Q on NM_001080850.3) | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.938); catalogued as rs774679471, COSV59604932; called by muse, mutect2, varscan2
- COL7A1 | c.1346G>A p.R449Q | Missense Mutation (SNP) | VAF 105/185 reads (57%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as rs764504901, COSV60404100; called by muse, mutect2, varscan2
- COPS9 | c.115G>A p.V39I (on ENST00000607357 / NM_001163424.2; = p.V70I on NM_138336.1) | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as rs1369380202, COSV56228451, COSV56229009, COSV56229090; called by muse, mutect2, varscan2
- CTNNA3 | c.1797T>G p.N599K | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV65624996; called by muse, mutect2, varscan2
- EGFL8 | c.628G>T p.A210S | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV61248796; called by muse, mutect2, varscan2
- FLG | c.4975G>A p.E1659K | Missense Mutation (SNP) | VAF 179/515 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.527); catalogued as COSV64251077; called by muse, mutect2, varscan2
- GPBP1L1 | c.301C>T p.R101* | Nonsense Mutation (SNP) | VAF 26/61 reads (43%) | catalogued as rs759018617, COSV51973736, COSV99322613; called by muse, mutect2, varscan2
- HADHA | c.410T>C p.I137T | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as rs1053616069, COSV66108791; called by muse, mutect2, varscan2
- HCN2 | c.1591G>A p.V531I | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52115360; called by muse, mutect2, varscan2
- HSPA2 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.67); catalogued as COSV55971455; called by muse, mutect2, varscan2
- IQCN | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 44/198 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as COSV66578650; called by muse, mutect2, varscan2
- KERA | c.508C>A p.L170I | Missense Mutation (SNP) | VAF 45/154 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV57132024; called by muse, mutect2, varscan2
- LAT | c.26G>A p.C9Y | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV57957015; called by muse, mutect2, varscan2
- MELTF | c.2096C>T p.A699V | Missense Mutation (SNP) | VAF 97/284 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs143354088; called by muse, mutect2, varscan2
- MEP1A | c.1205G>A p.R402H | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769871894, COSV57917827; called by muse, mutect2, varscan2
- MID1 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.07); catalogued as COSV58193387; called by muse, mutect2, varscan2
- MTMR12 | c.1512G>A p.M504I | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as COSV53788555; called by muse, mutect2, varscan2
- MYH7B | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as rs756100723, COSV53426270; called by muse, mutect2, varscan2
- OTUD7B | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 10/193 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as rs781977152, COSV64918013; called by muse, mutect2
- PIK3R6 | c.192G>A p.A64= | Splice Region (SNP) | VAF 30/90 reads (33%) | catalogued as rs149242502, COSV61006412; called by muse, mutect2, varscan2
- PNMA5 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.477); catalogued as rs782553555, COSV62625985; called by muse, varscan2
- PPP2R5D | c.668C>T p.S223F | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55151757; called by muse, mutect2, varscan2
- SALL3 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs1311177186, COSV73306259; called by muse, mutect2, varscan2
- SCAF4 | c.2554G>A p.A852T | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs920391064, COSV54255977; called by muse, mutect2, varscan2
- SCN5A | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); catalogued as rs746360906, COSV60068201; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SETBP1 | c.2722G>A p.D908N | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs559186877, COSV56312440; called by muse, mutect2, varscan2
- SLC13A1 | c.1512+1G>A p.X504_splice | Splice Site (SNP) | VAF 12/63 reads (19%) | catalogued as rs778055318, COSV52017610; called by muse, mutect2, varscan2
- STXBP5L | c.2371G>T p.A791S | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as rs751789410, COSV56537762; called by muse, mutect2, varscan2
- SYN3 | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141167959; called by muse, mutect2, varscan2
- TGM5 | c.775G>C p.V259L (on ENST00000220420 / NM_201631.4; = p.V177L on NM_004245.4) | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55012624; called by muse, mutect2, varscan2
- TIAM2 | c.5003C>G p.A1668G (on ENST00000529824; = p.A1639G on NM_012454.3) | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.292); catalogued as COSV51645189; called by muse, mutect2, varscan2
- TRDMT1 | c.287C>G p.T96R | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV58321118; called by muse, mutect2
- UGT2B7 | c.1037C>A p.T346N | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.258); catalogued as rs752827623, COSV59445800; called by muse, mutect2, varscan2
- ZNF286A | c.1178A>G p.H393R | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.991); catalogued as rs1401215175, COSV101224785; called by muse, mutect2, varscan2
- EEF1A1 | c.362_364del p.G121del | In Frame Del (DEL) | VAF 12/49 reads (24%) | called by mutect2, pindel, varscan2
- POC1B-GALNT4 | c.1464_1467del p.N488Kfs*3 | Frame Shift Del (DEL) | VAF 14/40 reads (35%) | called by pindel, varscan2
- ZNF569 | c.2058_2060del p.H686_*687delinsQ | Nonstop Mutation (DEL) | VAF 32/101 reads (32%) | called by mutect2, pindel, varscan2
- ADGRL4 | c.42G>A p.L14= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV66058684; called by muse, mutect2, varscan2
- ATP10B | c.2805C>T p.T935= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as rs765315343, COSV59150518; called by muse, mutect2, varscan2
- CD163L1 | c.3390C>T p.D1130= | Silent (SNP) | VAF 43/124 reads (35%) | catalogued as rs769675914, COSV58018746; called by muse, mutect2, varscan2
- ERICH3 | c.2907T>G p.G969= | Silent (SNP) | VAF 45/125 reads (36%) | catalogued as COSV58620400; called by muse, mutect2, varscan2
- FAM71C | c.720G>A p.E240= | Silent (SNP) | VAF 33/96 reads (34%) | catalogued as COSV60944610; called by muse, mutect2, varscan2
- GLI3 | c.2493C>T p.S831= | Silent (SNP) | VAF 54/205 reads (26%) | catalogued as COSV67888926; called by muse, mutect2, varscan2
- LRRC37A | c.4401G>T p.S1467= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV100208166; called by mutect2, varscan2
- MED13 | c.741G>A p.K247= | Silent (SNP) | VAF 6/65 reads (9%) | catalogued as COSV63228741; called by muse, mutect2
- OR8J3 | c.723C>T p.C241= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as rs760857965, COSV56879597, COSV56884655; called by muse, mutect2, varscan2
- PPP3R2 | c.327C>T p.N109= | Silent (SNP) | VAF 36/109 reads (33%) | catalogued as COSV62450353; called by muse, mutect2, varscan2
- TMPRSS6 | c.1257C>T p.A419= | Silent (SNP) | VAF 55/143 reads (38%) | catalogued as rs572632950, COSV60984542; called by muse, mutect2, varscan2
- ABHD3 | c.555+405T>A | Intron (SNP) | VAF 8/21 reads (38%) | catalogued as COSV100004394; called by muse, mutect2, varscan2
- ALMS1P1 | chr2:73700826 A>C | 3'Flank (SNP) | VAF 25/72 reads (35%) | catalogued as rs758804427; called by muse, mutect2, varscan2
- DLGAP1 | c.1592-14933dup | Intron (INS) | VAF 8/50 reads (16%) | called by mutect2, pindel, varscan2
- DNM1 | c.1335+1649G>A | Intron (SNP) | VAF 13/108 reads (12%) | catalogued as rs770984106, COSV100359938; called by muse, mutect2, varscan2
- OBSCN | c.18662-2114C>T | Intron (SNP) | VAF 18/47 reads (38%) | catalogued as rs765706284, COSV52802052; called by muse, mutect2, varscan2
